Somatic mutation profile of tumor specimen MP2PRT-PAVHMU-TMP1-A (aliquot MP2PRT-PAVHMU-TMP1-A-1-0-D-A819-36) from MP2PRT case MP2PRT-PAVHMU, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.2 years (1,155 days).
Specimen MP2PRT-PAVHMU-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 86e5a4e0-d057-4338-896a-dfb46841b49c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVHMU-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVHMU-NB1-A-1-0-D-A819-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2a1a3f36-65ba-427f-8765-ec1962aca030

The open-access MAF lists 22 somatic variants for this specimen: 14 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 7, Nonsense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL6A3 | c.2932G>A p.A978T | Missense Mutation (SNP) | VAF 165/385 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs768292803; ClinVar: uncertain significance; called by muse, varscan2
- H3C8 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 15/418 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.904); catalogued as COSV100010159, COSV59952645; called by muse, mutect2
- LRP1B | c.10310C>T p.S3437F | Missense Mutation (SNP) | VAF 69/245 reads (28%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.899); catalogued as COSV101260883; called by muse, mutect2, varscan2
- MTF1 | c.493C>T p.R165* | Nonsense Mutation (SNP) | VAF 16/426 reads (4%) | catalogued as COSV100888632; called by muse, mutect2
- OR52I2 | c.1012C>G p.L338V | Missense Mutation (SNP) | VAF 12/250 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.017); catalogued as COSV57046073; called by muse, mutect2
- RNF128 | c.689C>T p.S230F (on ENST00000255499 / NM_194463.2; = p.S204F on NM_024539.3) | Missense Mutation (SNP) | VAF 7/104 reads (7%) | SIFT tolerated (0.58); PolyPhen benign (0.005); catalogued as COSV55250486; called by muse, mutect2
- AMOTL2 | c.1737G>A p.M579I | Missense Mutation (SNP) | VAF 23/675 reads (3%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.995); called by muse, mutect2
- CBR1 | c.778G>C p.D260H | Missense Mutation (SNP) | VAF 15/422 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.376); called by muse, mutect2
- COL22A1 | c.3589C>G p.P1197A | Missense Mutation (SNP) | VAF 20/432 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.08); called by muse, mutect2
- CRYBG2 | c.83C>T p.T28I | Missense Mutation (SNP) | VAF 195/421 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- DEFB118 | c.31C>T p.L11F | Missense Mutation (SNP) | VAF 72/239 reads (30%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- GABRQ | c.1312C>G p.L438V | Missense Mutation (SNP) | VAF 19/530 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2
- MYH3 | c.4077G>T p.Q1359H | Missense Mutation (SNP) | VAF 214/523 reads (41%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZC3H7B | c.2668C>T p.R890W | Missense Mutation (SNP) | VAF 11/366 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); called by muse, mutect2
- CCDC57 | c.1488C>T p.L496= | Silent (SNP) | VAF 15/426 reads (4%) | catalogued as rs1258445900; called by muse, mutect2
- HLF | c.732C>T p.D244= | Silent (SNP) | VAF 155/340 reads (46%) | catalogued as rs532337710, COSV56832511; called by muse, mutect2, varscan2
- MGAT1 | c.39C>T p.G13= | Silent (SNP) | VAF 137/466 reads (29%) | catalogued as rs776454807, COSV57134754; called by muse, mutect2, varscan2
- MYO7A | c.5187G>A p.T1729= | Silent (SNP) | VAF 22/508 reads (4%) | catalogued as rs1456006525, COSV68686661; called by muse, mutect2
- RBP4 | c.258C>T p.D86= | Silent (SNP) | VAF 30/387 reads (8%) | called by muse, mutect2
- SYVN1 | c.567C>T p.F189= | Silent (SNP) | VAF 15/405 reads (4%) | called by muse, mutect2
- TMEM132A | c.1464G>A p.L488= (on ENST00000453848 / NM_178031.3; = p.L489= on NM_017870.4) | Silent (SNP) | VAF 26/839 reads (3%) | called by muse, mutect2
- BLOC1S2 | c.*517C>A | 3'UTR (SNP) | VAF 3/28 reads (11%) | called by muse, varscan2
